Somatic mutation profile of tumor specimen TARGET-10-PANYGB-09A (aliquot TARGET-10-PANYGB-09A-01D) from TARGET case TARGET-10-PANYGB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,788 days).
Specimen TARGET-10-PANYGB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6c310df-3a57-4095-8a32-d45b601c5e66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANYGB-14A (Bone Marrow Normal), aliquot TARGET-10-PANYGB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edf51547-226e-4338-8a72-fb061a358fdd

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS15 | c.2407G>T p.E803* | Nonsense Mutation (SNP) | VAF 51/127 reads (40%) | catalogued as COSV54509100; called by muse, mutect2, varscan2
- CDC42BPA | c.1670G>T p.R557L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as COSV62003014; called by muse, mutect2
- MPDZ | c.3814G>T p.D1272Y | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV59916797; called by muse, mutect2, varscan2
- SLC35G3 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV52011532; called by mutect2, varscan2
- ATMIN | c.840C>A p.D280E | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2
- EPM2AIP1 | c.1216G>T p.A406S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.069); called by muse, mutect2
- HIVEP2 | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HNRNPU | c.1943G>T p.G648V (on ENST00000283179; = p.G710V on NM_004501.3) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PROSER3 | c.920C>A p.A307D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.073); called by muse, mutect2
- ALOX12B | c.1497C>T p.R499= | Silent (SNP) | VAF 71/159 reads (45%) | catalogued as rs371016744, COSV100047733; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CAMKK2 | c.1482C>T p.R494= | Silent (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- CEP350 | c.2343C>A p.T781= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as rs1317014322; called by muse, mutect2
- NOL6 | c.2163G>T p.L721= | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- OGT | c.105A>T p.G35= | Silent (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
